Surgical pathology report (de-identified scan), TCGA case TCGA-N5-A4RS, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site MSKCC, specimen TCGA-N5-A4RS-01A (Primary Tumor).

[page 1 of 4]
+CD-3

Carcinosarcoma / Mixed Mullerian
Tumor, malignant 8950/3

Site C&F Uterus, NOS C55.9

path Endometrium C54.1

JW 4/2/13

Specimens Submitted:

- 1: SP: Uterus, cervix, bilateral fallopian tubes and ovaries
- 2: SP: Right para-aortic lymph nodes
- 3: SP: Left para-aortic lymph nodes
- 4: SP: Right external iliac lymph nodes
- 5: SP: Right obturator lymph nodes
- 6: SP: Right hypogastric lymph node
- 7: SP: Right common iliac lymph nodes
- 8: SP: Left obturator lymph nodes
- 9: SP: Left common iliac lymph nodes
- 10: SP: Left external iliac lymph nodes
- 11: SP: Left hypogastric lymph nodes

DIAGNOSIS:

- 1) UTERUS, CERVIX, FALLOPIAN TUBES AND OVARIES; TOTAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:
- CARCINOSARCOMA (MALIGNANT MIXED MULLERIAN TUMOR) OF ENDOMETRIUM, WITHOUT HETEROLOGOUS ELEMENTS.
- THE TUMOR INVADDES TO GREATER THAN HALF OF MYOMETRIUM.
- THE MAXIMAL THICKNESS OF MYOMETRIAL INVASION IS 9 MM.
- THE THICKNESS OF THE MYOMETRIUM IN THE AREA OF MAXIMAL TUMOR INVASION IS 15 MM.
- NO ENDOCERVICAL INVASION IS IDENTIFIED.
- VASCULAR INVASION IS PRESENT.
- THE ENDOMETRIUM IS UNREMARKABLE.
- THE MYOMETRIUM IS UNREMARKABLE.
- ALL ADNEXAE ARE UNREMARKABLE.
- BILATERAL PARACERVICAL SOFT TISSUE, NEGATIVE FOR TUMOR.
- 2) LYMPH NODES, RIGHT PARA-AORTIC; EXCISION:
- FOUR BENIGN LYMPH NODES (0/4).
- 3) LYMPH NODE, LEFT PARA-AORTIC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- FIBROADIPOSE TISSUE, NEGATIVE FOR METASTATIC TUMOR.

** Continued on next page **

[page 2 of 4]
-
- 4) LYMPH NODE, RIGHT EXTERNAL ILIAC; EXCISION:
- FIBROADIPOSE TISSUE, NEGATIVE FOR METASTATIC TUMOR.
- NO LYMPH NODES ARE IDENTIFIED.
- 5) LYMPH NODE, RIGHT OBTURATOR; EXCISION:
- FIBROADIPOSE TISSUE, NEGATIVE FOR METASTATIC TUMOR.
- NO LYMPH NODES ARE IDENTIFIED.
- 6) LYMPH NODES, RIGHT HYPOGASTRIC; EXCISION:
- THREE BENIGN LYMPH NODES (0/3).
- 7) LYMPH NODE, RIGHT COMMON ILIAC; EXCISION:
- FIBROADIPOSE TISSUE, NEGATIVE FOR METASTATIC TUMOR.
- NO LYMPH NODES ARE IDENTIFIED.
- 8) LYMPH NODES, RIGHT OBTURATOR; EXCISION:
- FOUR BENIGN LYMPH NODES (0/4).
- 9) LYMPH NODE, LEFT COMMON ILIAC; EXCISION:
- FIBROADIPOSE TISSUE, NEGATIVE FOR METASTATIC TUMOR.
- NO LYMPH NODES ARE IDENTIFIED, BUT DEEPER SECTIONS ARE PENDING.
- 10) LYMPH NODES, LEFT EXTERNAL ILIAC; EXCISION:
- THREE BENIGN LYMPH NODES (0/3).
- 11) LYMPH NODES, LEFT HYPOGASTRIC; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

[page 3 of 4]
[REDACTED]

Procedures/Addenda:
Addendum

[REDACTED]

Addendum Diagnosis

ADDENDUM

[REDACTED]

TISSUE SITE: LYMPH NODE, LEFT COMMON ILIAC

9) LYMPH NODE, LEFT COMMON ILIAC; EXCISION:
- DEEPER SECTIONS FAIL TO REVEAL A LYMPH NODE IN THE ENTIRELY
SUBMITTED SPECIMEN.

[REDACTED]

Addendum

[REDACTED]

[page 4 of 4]
[REDACTED]

Addendum Diagnosis

AS PER CLINICIAN'S REQUEST, ER AND PR IMMUNOHISTOCHEMICAL STAINS WERE PERFORMED ON THE UTERINE TUMOR WITH THE FOLLOWING RESULTS:

ER: NEGATIVE
PR: NEGATIVE

[REDACTED]

** End of Report **

Source: NCI Genomic Data Commons file bd57e823-259f-4c09-929c-eb9a6d3437af (TCGA-N5-A4RS.8748D172-D225-42D5-809C-54654425BF17.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).